Somatic mutation profile of tumor specimen 0DMRBA from CCDI case PBBYRL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.6 years (224 days).
Specimen 0DMRBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91ba718d-bb63-4b00-847c-86cdded1e801.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMRAN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e885208-f0f6-4424-af2a-a50434c61379

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PEX16 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 487/1188 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs749785179, COSV53799228; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 64/1939 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 74/2662 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MED13 | c.2957T>C p.M986T | Missense Mutation (SNP) | VAF 36/1366 reads (3%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.692); called by muse, mutect2
- OFD1 | c.1198_1199del p.V400Kfs*7 | Frame Shift Del (DEL) | VAF 419/639 reads (66%) | called by mutect2, pindel, varscan2
- NYX | c.381C>T p.H127= | Silent (SNP) | VAF 30/426 reads (7%) | catalogued as rs1281189925; called by muse, mutect2
- USF3 | c.3408A>T p.A1136= | Silent (SNP) | VAF 53/1599 reads (3%) | catalogued as COSV57072566; called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 5/84 reads (6%) | catalogued as COSV55814242; called by muse, mutect2
